Gene-level copy-number profile of tumor specimen 1105234 from CPTAC case C266664, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen 1105234: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0388f09d-ee69-47ba-9cd6-9916bff7d8c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105287 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/d0240eb9-7ea4-4d16-9425-283030253f94

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 516; copy number 1: 19,085; copy number 2: 35,223; copy number 3: 3,305; copy number 4: 734; copy number 5: 39; copy number 6: 12.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr13:20,221,962–20,232,365, 1 gene: GJB6.
- chr15:63,070,025–63,071,911, 1 gene (within-gene range 0–1): AC079328.2.
- chr21:10,649,400–10,649,835, 1 gene: IGHV1OR21-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 51 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:12,583,601–12,788,671, 4 genes, copy number 5 (within-gene range 4–5): RAF1, CRIP1P1, TMEM40, KRT18P17.
- chr5:34,158,121–34,244,796, 3 genes, copy number 6: AC139792.1, AC138409.2, AC138409.1.
- chr5:36,861,736–37,753,435, 16 genes, copy number 5 (within-gene range 3–5): AC026741.1, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P.
- chr8:17,469,518–17,800,917, 10 genes, copy number 5 (within-gene range 3–6): ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1.
- chr8:17,748,118–18,097,644, 10 genes, copy number 5–6: RNA5SP256, AC027117.2, AC027117.1, FGL1, AC087273.1, AC087273.2, PCM1, ASAH1, AC124242.1, AC124242.2.
- chr13:74,231,457–74,259,976, 1 gene, copy number 5: LINC00402.
- chr13:76,134,931–76,135,225, 1 gene, copy number 5: RN7SL571P.
- chr17:22,061,961–22,288,301, 6 genes, copy number 5: NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2.

Autosomal genes at a single copy (total copy number 1): 16,741. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
